Somatic mutation profile of tumor specimen TCGA-CS-5397-01A (aliquot TCGA-CS-5397-01A-01D-1893-08) from TCGA case TCGA-CS-5397, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 54.4 years (19,866 days).
Specimen TCGA-CS-5397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a2f7e95-6e99-48d8-8969-286fce8919f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5397-10A (Blood Derived Normal), aliquot TCGA-CS-5397-10A-03D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/591ee7cf-ef2e-4d1b-8f30-9200a042c503

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 14, Nonsense Mutation 3, Frame Shift Del 2, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs763895191, COSV53270277; called by muse, mutect2
- ANTXR1 | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58011094; called by muse, mutect2, varscan2
- CLTRN | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1307743076, COSV66711723; called by muse, mutect2, varscan2
- DMD | c.7652C>T p.T2551M | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778691311, COSV58900244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs116128702, COSV54201708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF6 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57403569; called by muse, mutect2, varscan2
- HAUS5 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV52547293; called by muse, mutect2, varscan2
- MAP7D2 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 111/383 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV65526306, COSV65526727; called by muse, mutect2, varscan2
- MTCL1 | c.4132G>A p.G1378R (on ENST00000306329 / NM_001378206.1; = p.G1059R on NM_015210.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV60404617; called by muse, mutect2, varscan2
- NF1 | c.3942G>A p.W1314* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as CM971045, CX111472, COSV62197621; called by muse, mutect2, varscan2
- OR4S1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1160718690, COSV60678887; called by muse, mutect2, varscan2
- OR8K1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs769004561, COSV54401922; called by muse, mutect2
- PLCH2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760532972, COSV53940727; called by muse, mutect2, varscan2
- PLEK | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52251123; called by muse, mutect2, varscan2
- PRKX | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53326790; called by muse, mutect2, varscan2
- PSD3 | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 82/287 reads (29%) | catalogued as COSV58965406; called by muse, mutect2, varscan2
- RRM1 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV56163717; called by muse, mutect2, varscan2
- SPACA3 | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52190781; called by muse, mutect2, varscan2
- TP53BP1 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV55498393; called by muse, mutect2, varscan2
- TRPC4AP | c.351G>T p.R117S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV52678178; called by muse, varscan2
- ULBP1 | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57663825; called by muse, mutect2, varscan2
- UNC13A | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.193); catalogued as COSV53191419; called by muse, mutect2, varscan2
- VGLL3 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs754406647, COSV67352675; called by muse, mutect2, varscan2
- WDFY3 | c.9194A>T p.E3065V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV55696693; called by muse, mutect2, varscan2
- ZBTB4 | c.1903_1905del p.E635del | In Frame Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs925281819; called by pindel, varscan2
- ZNF362 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV65031256; called by muse, mutect2, varscan2
- ZNF41 | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57441772; called by muse, mutect2, varscan2
- ZNF831 | c.5020G>A p.V1674I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64038620; called by muse, mutect2, varscan2
- GDPD3 | c.736del p.L246* | Frame Shift Del (DEL) | VAF 105/335 reads (31%) | called by mutect2, pindel, varscan2
- PCDHB1 | c.821del p.N274Tfs*4 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- AADACL4 | c.288G>A p.T96= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs539452254, COSV66105994; called by muse, mutect2, varscan2
- BCOR | c.2295C>T p.S765= | Silent (SNP) | VAF 107/329 reads (33%) | catalogued as rs1394435368, COSV60703621; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC14A | c.30G>T p.G10= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV60556467; called by muse, mutect2, varscan2
- DAB1 | c.42C>T p.S14= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs749634644, COSV59724931; called by muse, mutect2, varscan2
- FAM120A | c.3264C>T p.C1088= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV52902974; called by muse, mutect2
- FSTL5 | c.1056A>G p.R352= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV60186541; called by muse, mutect2, varscan2
- LLCFC1 | c.333G>A p.T111= (on ENST00000458732; = p.T80= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/237 reads (21%) | catalogued as rs1387721230, COSV62334034; called by muse, mutect2, varscan2
- MROH2B | c.990A>T p.R330= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV68182423; called by muse, mutect2, varscan2
- NOS1 | c.1917T>C p.N639= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV57609213; called by muse, mutect2, varscan2
- PDE6B | c.126G>A p.P42= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs533513647, COSV55325063; called by muse, mutect2, varscan2
- PKP2 | c.2019C>T p.G673= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs368325383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB3 | c.309C>T p.I103= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as rs1243750511, COSV52190449; called by muse, mutect2, varscan2
- SF3B1 | c.969T>C p.I323= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV59210498; called by muse, mutect2, varscan2
- ZNF202 | c.399G>T p.R133= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV60246770; called by muse, mutect2, varscan2
- ECPAS | chr9:111484366 A>C | 5'Flank (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52194208; called by muse, mutect2, varscan2
- LINC00922 | n.902C>T | RNA (SNP) | VAF 17/86 reads (20%) | catalogued as rs375252980; called by muse, mutect2, varscan2
